Somatic mutation profile of tumor specimen TARGET-20-PARZVE-03A (aliquot TARGET-20-PARZVE-03A-01D) from TARGET case TARGET-20-PARZVE, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.1 years (4,067 days).
Specimen TARGET-20-PARZVE-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c566b4cf-d97b-430f-98bc-626ef41bb3aa.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARZVE-14A (Bone Marrow Normal), aliquot TARGET-20-PARZVE-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3baceea7-45f3-46c0-a71b-12fef71f6070

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2028C>G p.N676K | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519766, COSV54042688, COSV54051954; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLT3 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV54046796; called by muse, mutect2
- STOX2 | c.-725C>T | 5'UTR (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
